Gene-level copy-number profile of tumor specimen TCGA-BK-A26L-01C from TCGA case TCGA-BK-A26L, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 71.2 years (26,002 days).
Specimen TCGA-BK-A26L-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.0a3da6e7-e5dd-4016-8637-987111d86c7c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BK-A26L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 392 have no estimate.
https://portal.gdc.cancer.gov/files/edd74dae-876e-4061-8625-65525a187819

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 1; copy number 2: 7,320; copy number 3: 17,088; copy number 4: 31,936; copy number 5: 2,706; copy number 6: 396; copy number 7: 26; copy number 8: 21; copy number 9: 98; copy number 12: 29; copy number 13: 3; copy number 17: 3; copy number 21: 25; copy number 22: 1; copy number 23: 9; copy number 24: 5; copy number 25: 34; copy number 38: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BK-A26L-01A-11D-A275-01): tumor purity 0.57, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:240,919,653–240,920,609, 1 gene: HNRNPA1P42.
- chr2:32,635,255–32,635,331, 1 gene: MIR4765.
- chr8:59,760,047–59,760,263, 1 gene: AC107934.1.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–4): AC092821.1, AC092821.2.
- chr13:68,985,058–68,986,064, 1 gene: ZDHHC20P4.
- chr21:31,038,159–31,063,168, 2 genes: KRTAP19-8, UBE3AP2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 208 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,081,831–130,201,336, 5 genes, copy number 24 (within-gene range 4–24): ALG1L2, LINC02014, FAM86HP, LINC02021, ENPP7P3.
- chr8:39,934,614–46,028,892, 93 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr9:673,478–685,555, 1 gene, copy number 12 (within-gene range 7–12): AL136979.1.
- chr9:2,228,961–2,229,241, 1 gene, copy number 9: RN7SL592P.
- chr9:5,629,025–5,856,426, 4 genes, copy number 9 (within-gene range 6–9): RIC1, AL136980.1, ERMP1, AK4P4.
- chr10:95,109,136–95,111,642, 1 gene, copy number 38: AL157834.1.
- chr12:122,834,453–122,862,961, 1 gene, copy number 22: HIP1R.
- chr15:25,201,323–25,250,940, 28 genes, copy number 12: SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr17:20,290,257–20,614,008, 34 genes, copy number 25: RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2, USP32P3, SRP68P3, AC015818.9, AC015818.10, NOS2P3, LGALS9B, TNPO1P3, YWHAEP3, KRT16P5, KRT16P3, AC015818.7, KRT17P6, KRT17P7, AC015818.6, AC015818.2, AC015818.5, TBC1D3P3, AC015818.8, AC015818.1, AC015818.3, COTL1P2, AC015818.4, CDRT15L2, ZSWIM5P2, MEIS3P2, AC087499.3, AC087499.1, AC087499.4.
- chr17:36,861,674–37,056,871, 9 genes, copy number 23 (within-gene range 3–23): LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5.
- chr17:37,140,611–37,163,139, 3 genes, copy number 17: AC244093.1, HMGB1P24, AC244093.2.
- chr17:39,626,740–40,093,867, 25 genes, copy number 21: PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA.
- chr19:45,071,500–45,092,635, 3 genes, copy number 13: ZNF296, GEMIN7-AS1, GEMIN7.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
